Somatic mutation profile of tumor specimen HCM-BROD-0869-C43-06A (aliquot HCM-BROD-0869-C43-06A-21D-A881-36) from HCMI case HCM-BROD-0869-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 45.7 years (16,703 days).
Specimen HCM-BROD-0869-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb6fd467-0f62-4255-96b8-3f6522fa3593.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0869-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0869-C43-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/708f3163-7530-437a-b1db-fe3faf63966f

The open-access MAF lists 34 somatic variants for this specimen: 18 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 14, Intron 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APCS | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 32/642 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs866542574, COSV54818126; called by muse, mutect2
- C5AR1 | c.56C>T p.T19I | Missense Mutation (SNP) | VAF 32/668 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs1202047995, COSV61893625; called by muse, mutect2
- CALML5 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 27/744 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); catalogued as rs1564480147; called by muse, mutect2
- CATSPER1 | c.509G>A p.G170D | Missense Mutation (SNP) | VAF 20/664 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV56413574; called by muse, mutect2
- ERMN | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 16/408 reads (4%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.714); catalogued as COSV68075248; called by muse, mutect2
- ISX | c.384C>A p.I128= | Splice Region (SNP) | VAF 23/326 reads (7%) | catalogued as COSV58085991; called by muse, mutect2
- MRGPRX2 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 18/613 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV61674565; called by muse, mutect2
- NTN4 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 22/640 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1276288998; called by muse, mutect2
- SLC35G2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as rs780945551, COSV67588733; called by muse, mutect2
- SPPL2B | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 29/893 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as COSV101476099; called by muse, mutect2
- ZNF497 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 52/1010 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV54050590; called by muse, mutect2
- ACSM4 | c.1391A>T p.Y464F | Missense Mutation (SNP) | VAF 23/420 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHD6 | c.6280G>C p.D2094H | Missense Mutation (SNP) | VAF 25/283 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL20A1 | c.3530G>A p.G1177E | Missense Mutation (SNP) | VAF 30/474 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HRH2 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 26/498 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NRG1 | c.1016C>T p.S339F (on ENST00000405005 / NM_013964.5; = p.S344F on NM_013956.5) | Missense Mutation (SNP) | VAF 18/433 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- NUMA1 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 37/674 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.124); called by muse, mutect2
- PCDHB16 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 21/657 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- COL4A5 | c.2109C>T p.I703= | Silent (SNP) | VAF 20/240 reads (8%) | catalogued as rs369092053; called by muse, mutect2
- CTNND2 | c.84G>A p.T28= | Silent (SNP) | VAF 30/484 reads (6%) | catalogued as rs762650023, COSV58891330; called by muse, mutect2
- GOLGB1 | c.8449T>C p.L2817= | Silent (SNP) | VAF 14/536 reads (3%) | called by muse, mutect2
- LRRC2 | c.423G>A p.Q141= | Silent (SNP) | VAF 24/404 reads (6%) | called by muse, mutect2
- METRN | c.672G>A p.Q224= | Silent (SNP) | VAF 48/844 reads (6%) | called by muse, mutect2
- MMP2 | c.1575G>A p.E525= | Silent (SNP) | VAF 24/420 reads (6%) | called by muse, mutect2
- MYMK | c.360C>T p.G120= | Silent (SNP) | VAF 51/618 reads (8%) | catalogued as COSV101301187; called by muse, mutect2
- PDZD2 | c.6276C>T p.I2092= | Silent (SNP) | VAF 34/578 reads (6%) | called by muse, mutect2
- PES1 | c.741C>T p.P247= | Silent (SNP) | VAF 34/562 reads (6%) | catalogued as rs775880048; called by muse, mutect2
- PLEKHG4B | c.2148G>A p.R716= (on ENST00000283426; = p.R1072= on NM_052909.5) | Silent (SNP) | VAF 46/758 reads (6%) | catalogued as COSV52047866; called by muse, mutect2
- PSD4 | c.63G>A p.L21= | Silent (SNP) | VAF 23/536 reads (4%) | called by muse, mutect2
- QRICH2 | c.3957C>T p.I1319= | Silent (SNP) | VAF 20/512 reads (4%) | catalogued as COSV53153100; called by muse, mutect2
- SGSH | c.834C>T p.F278= | Silent (SNP) | VAF 30/714 reads (4%) | called by muse, mutect2
- SPTA1 | c.4068C>T p.I1356= | Silent (SNP) | VAF 20/546 reads (4%) | catalogued as rs1209643854, COSV100934109, COSV100934758, COSV63749559; called by muse, mutect2
- TRIM54 | c.513+120G>A | Intron (SNP) | VAF 15/447 reads (3%) | called by muse, mutect2
- ZIC4 | c.-15-1280C>T | Intron (SNP) | VAF 22/374 reads (6%) | called by muse, mutect2
